Somatic mutation profile of tumor specimen C3N-02338-02 (aliquot CPT0136460009) from CPTAC case C3N-02338, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 58.7 years (21,451 days).
Specimen C3N-02338-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4410c97e-9959-4fdd-8bbd-47f7217b5672.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02338-71 (Blood Derived Normal), aliquot CPT0136570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f893b03e-01e7-46f2-b6cb-c1aa063a6aed

The open-access MAF lists 131 somatic variants for this specimen: 92 protein-altering or splice-affecting, 28 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 28, Nonsense Mutation 9, Intron 8, Frame Shift Del 7, Splice Site 6, Frame Shift Ins 4, Splice Region 4, 5'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD2 | c.2135C>A p.P712H | Missense Mutation (SNP) | VAF 114/631 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56647760; called by muse, mutect2, varscan2
- ARID1A | c.2830C>T p.Q944* | Nonsense Mutation (SNP) | VAF 17/268 reads (6%) | catalogued as COSV61374989; called by muse, mutect2
- ARID1A | c.5975C>G p.S1992* | Nonsense Mutation (SNP) | VAF 35/358 reads (10%) | catalogued as COSV61370542, COSV61371638, COSV61373486; called by muse, mutect2
- ASPM | c.9848C>T p.S3283F | Missense Mutation (SNP) | VAF 31/512 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs887239211; called by muse, mutect2
- BLM | c.953G>A p.C318Y | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV61925228; called by muse, mutect2
- CATSPERG | c.3001C>T p.H1001Y | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.566); catalogued as rs574265967, COSV53048937, COSV99285948; called by muse, mutect2, varscan2
- DGAT1 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV99045930; called by muse, mutect2, varscan2
- GART | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 57/366 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.612); catalogued as rs544071183, COSV67819004; called by muse, mutect2, varscan2
- IQGAP3 | c.4267C>T p.R1423C | Missense Mutation (SNP) | VAF 92/523 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs758045685; called by muse, mutect2, varscan2
- KDM5C | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 16/228 reads (7%) | catalogued as COSV64764982; called by muse, mutect2
- LHX6 | c.994T>C p.C332R (on ENST00000373755 / NM_001242334.2; = p.C361R on NM_014368.5) | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as rs1174667644; called by muse, mutect2, varscan2
- MAL | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs1189857522, COSV59431344; called by muse, mutect2, varscan2
- MAN1B1 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 28/518 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1432139879; called by muse, mutect2
- MCPH1 | c.2386G>A p.V796I | Missense Mutation (SNP) | VAF 63/356 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs374800057; called by muse, mutect2, varscan2
- MGMT | c.221C>T p.A74V (on ENST00000306010; = p.A43V on NM_002412.5) | Missense Mutation (SNP) | VAF 65/420 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs753839323; called by muse, mutect2, varscan2
- MPP2 | c.488G>C p.R163P (on ENST00000461854 / NM_001278372.2; = p.R139P on NM_005374.5) | Missense Mutation (SNP) | VAF 72/427 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs992935520, COSV52240301; called by muse, mutect2, varscan2
- NFIA | c.262C>G p.R88G | Missense Mutation (SNP) | VAF 54/359 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139262971, COSV64540979; called by muse, mutect2, varscan2
- PHF6 | c.35C>A p.T12K | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.017); catalogued as rs1569334235; called by muse, mutect2, varscan2
- QRICH2 | c.4477G>C p.G1493R | Missense Mutation (SNP) | VAF 81/513 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99429850; called by muse, mutect2, varscan2
- RBM12 | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs775097381, COSV58293638; called by muse, mutect2
- REPS1 | c.1971G>T p.P657= (on ENST00000450536 / NM_001286611.2; = p.P656= on NM_031922.4) | Splice Region (SNP) | VAF 23/333 reads (7%) | catalogued as COSV57808640, COSV57813531; called by muse, mutect2
- SEC23B | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 97/578 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.181); catalogued as rs1393165617; called by muse, mutect2, varscan2
- TOR1AIP1 | c.869G>A p.W290* | Nonsense Mutation (SNP) | VAF 44/254 reads (17%) | catalogued as COSV54870790; called by muse, mutect2, varscan2
- VHL | c.405_406dup p.F136Yfs*24 | Frame Shift Ins (INS) | VAF 58/334 reads (17%) | catalogued as COSV56553005; called by pindel, varscan2
- VHL | c.407_408insA p.F136Lfs*8 | Frame Shift Ins (INS) | VAF 90/375 reads (24%) | catalogued as COSV56573956; called by mutect2, varscan2*
- ZNF460 | c.1100G>C p.S367T | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs959464875; called by muse, mutect2, varscan2
- ZNF536 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 20/265 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62820557; called by muse, mutect2
- ACP6 | c.461T>G p.F154C | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADAMTS1 | c.2080G>T p.G694* | Nonsense Mutation (SNP) | VAF 50/227 reads (22%) | called by muse, mutect2, varscan2
- ADCY6 | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 93/471 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- AKAP13 | c.2404C>G p.L802V | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- ANKRD13C | c.473-2A>C p.X158_splice | Splice Site (SNP) | VAF 39/189 reads (21%) | called by muse, mutect2, varscan2
- AP2A2 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 40/618 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2
- AP3B1 | c.308T>A p.V103D | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ARHGAP21 | c.3539C>T p.T1180I | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP45 | c.79_90+25del p.X27_splice | Splice Site (DEL) | VAF 21/215 reads (10%) | called by mutect2, pindel
- ARMC8 | c.337+1G>A p.X113_splice (on ENST00000469044 / NM_001363941.2; = p.X99_splice on NM_014154.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 34/155 reads (22%) | called by muse, mutect2, varscan2
- BAP1 | c.1728A>T p.T576= | Splice Region (SNP) | VAF 38/392 reads (10%) | called by muse, mutect2
- BAP1 | c.846del p.E283Rfs*52 | Frame Shift Del (DEL) | VAF 48/504 reads (10%) | called by mutect2, pindel, varscan2
- COPG1 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.29); called by muse, mutect2
- EI24 | c.480G>C p.K160N | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- ELF1 | c.969del p.N324Ifs*14 | Frame Shift Del (DEL) | VAF 51/295 reads (17%) | called by mutect2, pindel, varscan2
- EMC2 | c.464A>G p.Q155R | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- FAM78B | c.516G>T p.W172C | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FPR3 | c.863G>A p.S288N | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- HEATR9 | c.1268T>A p.V423D | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- HGS | c.1330del p.Q444Sfs*41 | Frame Shift Del (DEL) | VAF 17/94 reads (18%) | called by mutect2, pindel, varscan2
- IFNA7 | c.353A>T p.D118V | Missense Mutation (SNP) | VAF 80/484 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.187G>C p.G63R | Missense Mutation (SNP) | VAF 112/618 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- ISOC2 | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 58/376 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITIH6 | c.3286A>C p.K1096Q | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KCNT1 | c.268C>G p.Q90E (on ENST00000488444; = p.Q109E on NM_020822.3) | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- KNL1 | c.4593del p.E1532Nfs*2 (on ENST00000346991 / NM_170589.5; = p.E1506Nfs*2 on NM_144508.5) | Frame Shift Del (DEL) | VAF 12/132 reads (9%) | called by mutect2, pindel
- KPNA7 | c.136A>C p.K46Q | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC7 | c.962T>G p.V321G (on ENST00000651989 / NM_001370785.2; = p.V288G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MACF1 | c.12670G>T p.E4224* (on ENST00000372915; = p.E2157* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 112/657 reads (17%) | called by muse, mutect2, varscan2
- MBOAT7 | c.254T>A p.F85Y | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPP7 | c.887+1G>T p.X296_splice | Splice Site (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2
- MRPL4 | c.482dup p.Y161* | Nonsense Mutation (INS) | VAF 58/333 reads (17%) | called by mutect2, pindel, varscan2
- NAIP | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDST1 | c.1976T>A p.M659K | Missense Mutation (SNP) | VAF 76/499 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOB1 | c.850T>C p.F284L | Missense Mutation (SNP) | VAF 11/277 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- NPLOC4 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 32/335 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); called by muse, mutect2
- OR5AK2 | c.524A>T p.N175I | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- P2RX1 | c.358-7C>T | Splice Region (SNP) | VAF 58/298 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 68/365 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PDZD4 | c.1221G>T p.R407S | Missense Mutation (SNP) | VAF 91/240 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLA2G2A | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 49/342 reads (14%) | called by muse, mutect2, varscan2
- POSTN | c.2179+5G>T | Splice Region (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- POTEJ | c.979_980dup p.Q327Hfs*4 | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | called by mutect2, varscan2
- PRAMEF19 | c.659T>C p.M220T | Missense Mutation (SNP) | VAF 90/665 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRMT3 | c.1553C>T p.T518I | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- RGCC | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RREB1 | c.1118_1121delinsGCG p.K373Sfs*38 | Frame Shift Del (DEL) | VAF 19/125 reads (15%) | called by pindel, varscan2*
- RTL1 | c.529A>T p.M177L | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SASS6 | c.1161C>G p.I387M | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SHANK1 | c.5482C>A p.P1828T | Missense Mutation (SNP) | VAF 46/576 reads (8%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.134); called by muse, mutect2
- SLAMF1 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 60/260 reads (23%) | called by muse, mutect2, varscan2
- SLC4A1AP | c.209T>A p.L70H | Missense Mutation (SNP) | VAF 86/403 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SMARCA5 | c.419+2T>A p.X140_splice | Splice Site (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- SNX14 | c.107_108insG p.C37Lfs*10 | Frame Shift Ins (INS) | VAF 43/351 reads (12%) | called by mutect2, pindel, varscan2
- SPTA1 | c.3715-1G>C p.X1239_splice | Splice Site (SNP) | VAF 56/268 reads (21%) | called by muse, mutect2, varscan2
- SRRM3 | c.1427_1436delinsGCCGT p.A476Gfs*67 | Frame Shift Del (DEL) | VAF 26/220 reads (12%) | called by pindel, varscan2*
- SRSF10 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- SUGP2 | c.1366A>T p.M456L | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNJ2 | c.305del p.T102Mfs*17 | Frame Shift Del (DEL) | VAF 51/333 reads (15%) | called by mutect2, pindel, varscan2
- TEX15 | c.4682T>A p.I1561K (on ENST00000256246; = p.I1944K on NM_001350162.2) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2
- TIAM1 | c.2380A>C p.I794L | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TRRAP | c.10740G>T p.Q3580H (on ENST00000359863 / NM_001244580.1; = p.Q3551H on NM_003496.3) | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- VSIG1 | c.622T>C p.Y208H | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- VSTM2L | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZNF208 | c.3037T>C p.S1013P | Missense Mutation (SNP) | VAF 29/538 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.634); called by muse, mutect2
- ACE | c.1761C>T p.D587= | Silent (SNP) | VAF 52/675 reads (8%) | catalogued as rs765157268; called by muse, mutect2
- ADAMTS9 | c.2634G>A p.Q878= | Silent (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2
- AHRR | c.1359G>A p.P453= | Silent (SNP) | VAF 68/319 reads (21%) | catalogued as rs370755723; called by muse, mutect2, varscan2
- ATRN | c.1182T>C p.G394= | Silent (SNP) | VAF 37/254 reads (15%) | called by muse, mutect2, varscan2
- C10orf67 | c.378G>A p.Q126= (on ENST00000323327; = p.Q127= on NM_153714.3) | Silent (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- C16orf90 | c.258C>T p.G86= (on ENST00000399645 / NM_001353385.2; = p.G77= on NM_001080524.2) | Silent (SNP) | VAF 80/347 reads (23%) | called by muse, mutect2, varscan2
- CSMD1 | c.2982C>G p.S994= (on ENST00000520002; = p.S993= on NM_033225.6) | Silent (SNP) | VAF 92/544 reads (17%) | catalogued as rs372606827; called by muse, varscan2
- CSNK1G2 | c.1053C>G p.L351= | Silent (SNP) | VAF 60/359 reads (17%) | catalogued as rs1484315004; called by muse, mutect2, varscan2
- DPCD | c.279C>T p.F93= | Silent (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- EEF1A1 | c.789T>C p.P263= | Silent (SNP) | VAF 25/147 reads (17%) | called by muse, mutect2, varscan2
- HSPG2 | c.11766G>A p.E3922= | Silent (SNP) | VAF 68/459 reads (15%) | called by muse, mutect2, varscan2
- IRF8 | c.759G>A p.P253= | Silent (SNP) | VAF 68/331 reads (21%) | catalogued as rs747312747, COSV51897709; called by muse, mutect2, varscan2
- JAKMIP2 | c.2340C>T p.A780= | Silent (SNP) | VAF 12/308 reads (4%) | called by muse, mutect2
- KCNT2 | c.1176G>A p.R392= | Silent (SNP) | VAF 8/187 reads (4%) | catalogued as rs1250063920; called by muse, mutect2
- KIF20B | c.1095T>A p.S365= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- MACF1 | c.3966A>G p.L1322= | Silent (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- MCUB | c.81G>A p.P27= | Silent (SNP) | VAF 21/111 reads (19%) | called by muse, mutect2, varscan2
- MYH3 | c.5130C>T p.S1710= | Silent (SNP) | VAF 146/812 reads (18%) | catalogued as rs373468193; called by muse, mutect2, varscan2
- PATZ1 | c.1068T>C p.A356= | Silent (SNP) | VAF 50/281 reads (18%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1824G>A p.S608= | Silent (SNP) | VAF 116/728 reads (16%) | catalogued as COSV65341577, COSV65342370; called by muse, mutect2, varscan2
- PLEC | c.5121G>T p.A1707= (on ENST00000322810 / NM_201380.4; = p.A1597= on NM_000445.5) | Silent (SNP) | VAF 233/929 reads (25%) | called by muse, mutect2, varscan2
- RAB34 | c.609G>A p.E203= | Silent (SNP) | VAF 53/258 reads (21%) | called by muse, mutect2, varscan2
- RGMA | c.210C>T p.D70= | Silent (SNP) | VAF 53/221 reads (24%) | catalogued as rs751777604; called by muse, mutect2, varscan2
- SLAMF8 | c.375G>A p.V125= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV99223002; called by muse, varscan2
- SND1 | c.1692C>G p.A564= | Silent (SNP) | VAF 43/227 reads (19%) | called by muse, mutect2, varscan2
- SNRPG | c.21C>A p.P7= | Silent (SNP) | VAF 35/297 reads (12%) | called by muse, mutect2, varscan2
- TIGD3 | c.372G>A p.L124= | Silent (SNP) | VAF 49/250 reads (20%) | catalogued as COSV99361864; called by muse, mutect2, varscan2
- ZNF638 | c.4749G>A p.K1583= | Silent (SNP) | VAF 48/223 reads (22%) | called by muse, mutect2, varscan2
- AGGF1 | c.-257A>T | 5'UTR (SNP) | VAF 77/415 reads (19%) | called by muse, mutect2, varscan2
- AMT | c.259-29T>G | Intron (SNP) | VAF 72/344 reads (21%) | called by muse, mutect2, varscan2
- CDKN2D | c.-11C>A | 5'UTR (SNP) | VAF 27/138 reads (20%) | called by muse, mutect2, varscan2
- ETS2 | c.-150-10G>A | Intron (SNP) | VAF 42/289 reads (15%) | called by muse, mutect2, varscan2
- NOP56 | c.570-157C>T | Intron (SNP) | VAF 18/292 reads (6%) | called by muse, mutect2
- NTNG2 | c.1054+800C>A | Intron (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- SCN1A | c.264+36T>C | Intron (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- SNX13 | c.-170C>A | 5'UTR (SNP) | VAF 55/255 reads (22%) | called by muse, mutect2, varscan2
- SPHK1 | c.10+120G>T | Intron (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- SPHK1 | c.10+121A>G | Intron (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.6790+39C>T | Intron (SNP) | VAF 27/133 reads (20%) | called by mutect2, varscan2
